Somatic mutation profile of tumor specimen 0DK0AJ from CCDI case PBBXRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 17.5 years (6,392 days).
Specimen 0DK0AJ: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8c98cc8-54ee-49d3-a2d5-bf50599a7bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK0AQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/206912ef-c94d-42a3-acd2-2afef3fca59f

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 3, 3'UTR 1, 5'Flank 1, Frame Shift Del 1, Nonstop Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNT12 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 150/684 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs777862536; called by muse, mutect2, varscan2
- LRRK2 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 44/601 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.287); catalogued as rs201333920, COSV54144409; called by muse, mutect2
- OR8G5 | c.935G>C p.*312Sext*5 | Nonstop Mutation (SNP) | VAF 42/363 reads (12%) | catalogued as COSV58382761; called by muse, varscan2
- SLITRK3 | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 120/577 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1381358755, COSV53850229; called by muse, mutect2, varscan2
- STEAP4 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 99/1036 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57329100; called by muse, mutect2
- TTC25 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 164/798 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs782453829; called by muse, varscan2
- ABCB8 | c.1964A>C p.D655A (on ENST00000297504 / NM_001282291.2; = p.D638A on NM_007188.5) | Missense Mutation (SNP) | VAF 132/500 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ANPEP | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 191/750 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL35 | c.134_150del p.L45Rfs*147 | Frame Shift Del (DEL) | VAF 61/337 reads (18%) | called by mutect2, pindel, varscan2
- PPIL2 | c.32+1G>A p.X11_splice | Splice Site (SNP) | VAF 46/524 reads (9%) | called by muse, mutect2
- WFS1 | c.2525T>G p.L842R | Missense Mutation (SNP) | VAF 66/757 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WNT5A | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 52/531 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOK6 | c.372C>A p.P124= | Silent (SNP) | VAF 106/458 reads (23%) | catalogued as rs368721580, COSV66927938; called by muse, mutect2, varscan2
- OTOP2 | c.1665G>T p.L555= | Silent (SNP) | VAF 83/735 reads (11%) | called by muse, mutect2, varscan2
- PTPRF | c.1278C>T p.S426= | Silent (SNP) | VAF 125/713 reads (18%) | catalogued as rs556161672, COSV63442617; called by muse, mutect2, varscan2
- RBM20 | c.2358C>T p.D786= | Silent (SNP) | VAF 126/546 reads (23%) | catalogued as rs1045844360; ClinVar: likely benign; called by muse, mutect2, varscan2
- C3orf62 | c.*75C>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | catalogued as rs1007386943; called by muse, mutect2
- CPNE4 | chr3:132037580 G>A | 5'Flank (SNP) | VAF 50/712 reads (7%) | called by muse, mutect2
- KLRD1 | c.100+26T>G | Intron (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- MUC19 | n.20636G>A | RNA (SNP) | VAF 50/673 reads (7%) | called by muse, mutect2
- RBMS1 | c.901-18A>G | Intron (SNP) | VAF 50/562 reads (9%) | called by muse, mutect2
- TMC3 | c.313-76T>C | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
